Somatic mutation profile of tumor specimen TARGET-20-PATDLI-09A (aliquot TARGET-20-PATDLI-09A-01D) from TARGET case TARGET-20-PATDLI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,905 days).
Specimen TARGET-20-PATDLI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd9b9905-e553-4faa-a038-02d504153646.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDLI-14A (Bone Marrow Normal), aliquot TARGET-20-PATDLI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8880c4d-747f-4152-b6d8-27842baa9367

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>A p.N676K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 13/35 reads (37%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 45/224 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1355A>G p.D452G | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.618); catalogued as rs121907902, CM910412, COSV60070732; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4428+1G>A p.X1476_splice (on ENST00000378444 / NM_001123385.2; = p.X1442_splice on NM_017745.6) | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV60715599; called by muse, mutect2, varscan2
- TET2 | c.3784C>T p.R1262W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361899165, COSV54399852; called by muse, mutect2, varscan2
- TET2 | c.1107G>T p.R369= | Silent (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
